Somatic mutation profile of tumor specimen 0DKIIG from CCDI case PBBYHH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 7.4 years (2,700 days).
Specimen 0DKIIG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eddadf4e-8774-4a3d-85e5-050c4242e969.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKIHU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55c6fe1b-f2c9-4956-b08f-93c6deb60da9

The open-access MAF lists 16 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 4, 3'UTR 2, Nonsense Mutation 1, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CALM1 | c.413A>G p.N138S | Missense Mutation (SNP) | VAF 104/306 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.076); catalogued as COSV63663757; called by muse, mutect2, varscan2
- COL6A5 | c.7411C>T p.R2471* (on ENST00000312481; = p.R2467* on NM_153264.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 43/645 reads (7%) | catalogued as rs753445274, COSV55209184; called by muse, mutect2
- HECW1 | c.2296G>A p.A766T | Missense Mutation (SNP) | VAF 67/332 reads (20%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs953667034, COSV101223049, COSV67822507, COSV67839582; called by muse, mutect2, varscan2
- PCSK5 | c.5159G>T p.C1720F | Missense Mutation (SNP) | VAF 22/378 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs774878829; called by muse, mutect2
- LACRT | c.123T>G p.N41K | Missense Mutation (SNP) | VAF 108/702 reads (15%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MS4A4A | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 42/464 reads (9%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.973); called by muse, mutect2
- PIK3C2G | c.2449C>A p.Q817K (on ENST00000676171; = p.Q776K on NM_004570.5) | Missense Mutation (SNP) | VAF 74/1122 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2
- TET2 | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 32/726 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.086); called by muse, mutect2
- C10orf62 | c.120C>T p.S40= | Silent (SNP) | VAF 18/297 reads (6%) | catalogued as rs1204503287; called by muse, mutect2
- FADS2 | c.741C>T p.I247= | Silent (SNP) | VAF 92/424 reads (22%) | catalogued as rs1177782423; called by muse, mutect2, varscan2
- TRH | c.564G>A p.P188= | Silent (SNP) | VAF 76/295 reads (26%) | catalogued as rs767305675; called by muse, mutect2, varscan2
- ZNF268 | c.2625G>A p.R875= | Silent (SNP) | VAF 125/1206 reads (10%) | called by muse, mutect2, varscan2
- BNIP2 | chr15:59689465 del GG | 5'Flank (DEL) | VAF 59/129 reads (46%) | called by mutect2, pindel, varscan2
- EDA | c.*9C>A | 3'UTR (SNP) | VAF 15/274 reads (5%) | catalogued as rs1429575806; called by muse, mutect2
- EHMT1 | c.1647+72G>A | Intron (SNP) | VAF 17/144 reads (12%) | catalogued as rs1479386174; called by muse, mutect2, varscan2
- XKR8 | c.*5A>G | 3'UTR (SNP) | VAF 86/416 reads (21%) | called by muse, mutect2
